Somatic mutation profile of tumor specimen MP2PRT-PASGWX-TMP1-A (aliquot MP2PRT-PASGWX-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASGWX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,744 days).
Specimen MP2PRT-PASGWX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d86fa75-93e9-4470-897d-ebfc8b88bfc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGWX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGWX-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94c655a0-aa55-4ee0-aedd-b1eaaf2ea4c1

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 124/424 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 168/504 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs782110668, COSV61526536; called by muse, mutect2, varscan2
- COL9A3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 217/555 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs778300099, COSV59655552; called by muse, mutect2, varscan2
- DLG5 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 201/600 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64946873, COSV64947137; called by muse, mutect2, varscan2
- KCNJ12 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 47/1621 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as rs374903521; called by muse, mutect2
- KMT5B | c.1400del p.S467* | Frame Shift Del (DEL) | VAF 108/363 reads (30%) | called by mutect2, pindel, varscan2
- LY6G5C | c.418_426dup p.L142_E143insGLL (on ENST00000375863; = p.L67_E68insGLL on NM_025262.3) | In Frame Ins (INS) | VAF 188/630 reads (30%) | called by mutect2, varscan2
- HECW1 | c.1815G>A p.T605= | Silent (SNP) | VAF 242/720 reads (34%) | catalogued as COSV67821821; called by muse, varscan2
- TENM2 | c.6912C>T p.G2304= (on ENST00000518659 / NM_001122679.2; = p.G2065= on NM_001080428.3) | Silent (SNP) | VAF 221/616 reads (36%) | catalogued as rs748674086; called by muse, mutect2, varscan2
- VCX3A | c.207C>T p.S69= | Silent (SNP) | VAF 126/965 reads (13%) | catalogued as rs1441554223; called by muse, mutect2, varscan2
